CCDI case PBBZMC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/b7653d52-5e8f-45c0-b3fe-290d1fa192eb

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 10.0 years (3,667 days).

Biospecimens (2 samples)
- Sample 0DMKKG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
